Somatic mutation profile of tumor specimen TCGA-TM-A84J-01A (aliquot TCGA-TM-A84J-01A-11D-A36O-08) from TCGA case TCGA-TM-A84J, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.2 years (23,091 days).
Specimen TCGA-TM-A84J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 385285f5-4512-4cab-af0d-52c696d1f0a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84J-10A (Blood Derived Normal), aliquot TCGA-TM-A84J-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b648ce0-bf6c-4a45-9788-08f64fc3d15e

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, RNA 3, Frame Shift Del 1, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 32/35 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- ABCA3 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1422450809, COSV100068386; called by muse, mutect2, varscan2
- ABCA7 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99565652; called by muse, mutect2, varscan2
- ADGRL2 | c.1948G>T p.V650F (on ENST00000370717 / NM_001366005.1; = p.V637F on NM_012302.4) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99588637; called by muse, mutect2, varscan2
- AMZ1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1422236809, COSV100406350; called by muse, mutect2, varscan2
- AP3D1 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs753212898, COSV61425304; called by muse, mutect2, varscan2
- AQP2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as rs778056386, COSV99550808; called by muse, mutect2, varscan2
- CDC123 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 80/813 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99826861; called by muse, mutect2, varscan2
- CEP68 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs201157959, COSV99560867; called by muse, mutect2, varscan2
- DENND4A | c.4730C>G p.S1577C | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs778895336, COSV101475322; called by muse, mutect2, varscan2
- DNAH9 | c.12172C>T p.H4058Y | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99305560; called by muse, mutect2, varscan2
- DNAJC12 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99830576; called by muse, mutect2, varscan2
- FABP4 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV99808517; called by muse, mutect2, varscan2
- FAM114A1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs914192852, COSV100729282; called by muse, mutect2, varscan2
- FAM76B | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs1260971443, COSV100716440; called by muse, mutect2, varscan2
- FBXO47 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100960492; called by muse, mutect2, varscan2
- GLB1L | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99850498; called by muse, mutect2, varscan2
- IPP | c.1502A>G p.H501R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100739512; called by muse, mutect2, varscan2
- LRP2 | c.10652G>A p.R3551H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs545303364, COSV55548085; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MRPL27 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs148980265; called by muse, mutect2, varscan2
- NCAPD3 | c.567+2T>G p.X189_splice | Splice Site (SNP) | VAF 35/105 reads (33%) | catalogued as COSV101596365; called by muse, mutect2, varscan2
- NDST1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs746022379, COSV55790987; called by muse, mutect2, varscan2
- PCDHAC1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.491); catalogued as COSV99165937; called by muse, mutect2, varscan2
- TDP1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113382706, COSV100187755; called by muse, mutect2, varscan2
- ZNF124 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517749; called by muse, mutect2, varscan2
- ATM | c.4048_4050del p.T1350del | In Frame Del (DEL) | VAF 65/71 reads (92%) | called by mutect2, pindel, varscan2
- DUSP5 | c.413_414del p.E138Vfs*14 | Frame Shift Del (DEL) | VAF 49/96 reads (51%) | called by mutect2, pindel, varscan2
- IGHV1-18 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- APOL5 | c.120G>A p.G40= | Silent (SNP) | VAF 187/392 reads (48%) | catalogued as COSV50767231; called by muse, mutect2, varscan2
- ASNS | c.1398A>G p.P466= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99446234; called by muse, mutect2, varscan2
- CYP4A22 | c.564C>T p.H188= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs865887358, COSV99594834; called by muse, mutect2, varscan2
- DCST2 | c.720G>A p.A240= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1310720376, COSV55050807, COSV99791864; called by muse, mutect2, varscan2
- DENND2C | c.2496T>C p.H832= (on ENST00000393274 / NM_001256404.2; = p.H775= on NM_198459.4) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101283920; called by muse, mutect2, varscan2
- GGCX | c.1077C>T p.R359= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99289862; called by muse, mutect2, varscan2
- MYO3A | c.4488C>T p.P1496= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV56320742, COSV99779441; called by muse, mutect2, varscan2
- NISCH | c.3780G>T p.R1260= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs761715632, COSV100401630; called by muse, mutect2, varscan2
- OR2T27 | c.864C>G p.L288= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100788220; called by muse, mutect2, varscan2
- SEMA3B | c.1734C>T p.H578= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- SIRT7 | c.729G>A p.G243= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV58712861; called by muse, mutect2, varscan2
- TANC2 | c.3345C>T p.T1115= | Silent (SNP) | VAF 72/145 reads (50%) | catalogued as rs372775570; called by muse, mutect2, varscan2
- TRPV1 | c.1113C>T p.T371= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs568215049, COSV99439436; called by muse, mutect2, varscan2
- ZNF671 | c.783C>T p.A261= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100235000; called by muse, mutect2, varscan2
- DCHS2 | n.5320C>T | RNA (SNP) | VAF 21/93 reads (23%) | catalogued as rs1187560118, COSV100601658; called by muse, mutect2, varscan2
- MIR519B | n.27G>A | RNA (SNP) | VAF 103/184 reads (56%) | catalogued as rs755667802; called by muse, mutect2, varscan2
- OR2U1P | n.311C>T | RNA (SNP) | VAF 54/248 reads (22%) | catalogued as rs369399120; called by muse, mutect2, varscan2
- PRR12 | c.52-230A>G | Intron (SNP) | VAF 10/22 reads (45%) | catalogued as rs1374490875, COSV101330652; called by muse, mutect2, varscan2
